Somatic mutation profile of tumor specimen TCGA-HT-7477-01B (aliquot TCGA-HT-7477-01B-11D-A289-08) from TCGA case TCGA-HT-7477, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 62.8 years (22,948 days).
Specimen TCGA-HT-7477-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f33a073-6e54-41e4-8dec-6ab0deaf4be2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7477-10A (Blood Derived Normal), aliquot TCGA-HT-7477-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f746ae80-fd31-4887-8314-73202ca95ae8

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 11, Splice Region 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.595-2A>C p.X199_splice | Splice Site (SNP) | VAF 48/53 reads (91%) | hotspot (GDC flag); catalogued as COSV64870599, COSV64883090, COSV64883867; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/53 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 76/86 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAM2 | c.1311A>G p.L437= | Splice Region (SNP) | VAF 78/164 reads (48%) | catalogued as rs778495497, COSV55868097; called by muse, mutect2, varscan2
- ANKMY1 | c.680A>C p.K227T | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56040621; called by muse, mutect2, varscan2
- CARD11 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62753847; called by muse, mutect2, varscan2
- CDH9 | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV50270199, COSV99163202; called by muse, mutect2, varscan2
- DBNL | c.545A>G p.K182R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV51979649; called by muse, mutect2, varscan2
- DLGAP5 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55961969; called by muse, mutect2, varscan2
- DNAH7 | c.5693C>T p.T1898I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV56784904; called by muse, mutect2, varscan2
- DNAI2 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs372196782; called by muse, mutect2
- DPYS | c.575A>T p.H192L | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100680009; called by muse, mutect2
- FAT3 | c.13420G>T p.V4474L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV53171325; called by muse, mutect2, varscan2
- FCRL5 | c.819C>A p.S273R | Missense Mutation (SNP) | VAF 141/294 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100708853, COSV62519948; called by muse, mutect2, varscan2
- FPGS | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs377363236; called by muse, mutect2, varscan2
- FUT10 | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV59454182; called by muse, mutect2, varscan2
- GPR45 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV51526156; called by muse, mutect2, varscan2
- MYO15A | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs764355744, COSV52762587; called by muse, mutect2, varscan2
- NBEAL2 | c.2426T>C p.F809S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52762649; called by muse, mutect2, varscan2
- NUDT19 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs746432144, COSV67959888; called by muse, mutect2, varscan2
- OR4S2 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56746271; called by muse, mutect2, varscan2
- OR51D1 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62914831; called by muse, mutect2, varscan2
- P2RY12 | c.530T>A p.F177Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV56396298; called by muse, mutect2, varscan2
- RGS12 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60910052; called by muse, mutect2, varscan2
- RIMS1 | c.2854C>T p.R952C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53447605, COSV53473573; called by muse, mutect2, varscan2
- RYR2 | c.7193T>C p.L2398P | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63712355; called by muse, mutect2, varscan2
- SLC26A2 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as rs748164269, COSV53826729; called by muse, mutect2, varscan2
- SPATA2 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV56865266; called by muse, mutect2, varscan2
- TRIML2 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.786); catalogued as COSV58719308; called by muse, mutect2, varscan2
- TTK | c.537G>A p.M179I | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV57884918; called by muse, mutect2, varscan2
- TTN | c.20180C>T p.P6727L (on ENST00000591111; = p.P5800L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/21 reads (62%) | PolyPhen benign (0.328); catalogued as COSV60334400; called by muse, mutect2, varscan2
- ZER1 | c.1696C>T p.L566F | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52565833; called by muse, mutect2, varscan2
- ZGRF1 | c.5210G>T p.G1737V | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV71393793; called by muse, mutect2, varscan2
- IGKV6D-21 | c.338T>C p.L113S | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACTRT1 | c.810C>A p.I270= | Silent (SNP) | VAF 51/80 reads (64%) | catalogued as COSV64420015; called by muse, mutect2, varscan2
- BBS12 | c.1851A>G p.T617= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs369934327; called by muse, mutect2, varscan2
- EGFLAM | c.228C>T p.G76= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs142461042; called by muse, mutect2, varscan2
- FRYL | c.6604C>T p.L2202= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as COSV51961817; called by muse, mutect2, varscan2
- PGK2 | c.795C>T p.I265= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs774299538, COSV59162610; called by muse, mutect2, varscan2
- PLAC9 | c.84T>A p.P28= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV64840741; called by muse, mutect2, varscan2
- PSD3 | c.843A>T p.P281= | Silent (SNP) | VAF 24/141 reads (17%) | catalogued as COSV58978856; called by muse, mutect2, varscan2
- PTGS2 | c.1572T>C p.V524= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV66569029, COSV66571716; called by muse, mutect2, varscan2
- SCUBE1 | c.2556C>T p.G852= | Silent (SNP) | VAF 46/61 reads (75%) | catalogued as rs1391061004, COSV62612661; called by muse, mutect2, varscan2
- TRIP6 | c.342G>A p.A114= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1275577992, COSV51936827; called by muse, mutect2, varscan2
- TUBGCP3 | c.1488T>G p.V496= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV56191284; called by muse, mutect2, varscan2
- SNORD114-6 | n.64G>A | RNA (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
